Somatic mutation profile of tumor specimen TCGA-AN-A0FL-01A (aliquot TCGA-AN-A0FL-01A-11W-A050-09) from TCGA case TCGA-AN-A0FL, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 62.4 years (22,805 days).
Specimen TCGA-AN-A0FL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 48eafcd5-7af9-4648-b2b5-501ac3ad0212.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AN-A0FL-10A (Blood Derived Normal), aliquot TCGA-AN-A0FL-10A-01W-A055-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/028b925e-5e27-4624-a4e1-7c30ffde9012

The open-access MAF lists 179 somatic variants for this specimen: 138 protein-altering or splice-affecting, 37 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 113, Silent 37, Nonsense Mutation 10, Frame Shift Del 6, Splice Site 4, Splice Region 2, In Frame Del 2, RNA 2, Frame Shift Ins 1, Intron 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR2 | c.1647T>G p.N549K | Missense Mutation (SNP) | VAF 85/131 reads (65%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913476, COSV60638757, COSV60639738; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.673-2A>G p.X225_splice | Splice Site (SNP) | VAF 77/95 reads (81%) | hotspot (GDC flag); catalogued as rs1555525585, CS109519, COSV52669186, COSV52682653, COSV52687702; ClinVar: likely pathogenic / pathogenic / not provided; called by muse, mutect2, varscan2
- AF196969.1 | c.208G>T p.A70S | Missense Mutation (SNP) | VAF 144/334 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.506); catalogued as rs782423797, COSV52141471; called by muse, mutect2, varscan2
- AFF3 | c.1441C>A p.P481T | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT tolerated (0.58); PolyPhen benign (0.419); catalogued as COSV57845289; called by muse, mutect2, varscan2
- AMBRA1 | c.3691G>C p.A1231P (on ENST00000458649 / NM_001367468.1; = p.A1141P on NM_017749.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.093); catalogued as COSV54050325; called by muse, mutect2, varscan2
- ANK2 | c.6282A>T p.E2094D | Missense Mutation (SNP) | VAF 42/150 reads (28%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.593); catalogued as COSV52151410; called by muse, mutect2, varscan2
- ARHGAP17 | c.1682C>T p.S561F | Missense Mutation (SNP) | VAF 35/76 reads (46%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.34); catalogued as COSV51505592; called by muse, mutect2, varscan2
- ARHGAP29 | c.1503G>C p.E501D | Missense Mutation (SNP) | VAF 100/179 reads (56%) | SIFT tolerated (0.6); PolyPhen benign (0.007); catalogued as COSV53109628; called by muse, mutect2, varscan2
- ASIC1 | c.866C>T p.T289I | Missense Mutation (SNP) | VAF 74/194 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as COSV57316674; called by muse, mutect2, varscan2
- ASPA | c.492T>A p.Y164* | Nonsense Mutation (SNP) | VAF 97/113 reads (86%) | catalogued as COSV53980438; called by muse, mutect2, varscan2
- ASTN1 | c.554G>A p.R185Q | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.986); catalogued as COSV56064345; called by muse, mutect2, varscan2
- ATG3 | c.559G>C p.D187H | Missense Mutation (SNP) | VAF 93/292 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.726); catalogued as COSV51926239; called by muse, mutect2, varscan2
- BCL2L12 | c.58G>T p.E20* | Nonsense Mutation (SNP) | VAF 6/32 reads (19%) | catalogued as COSV55862637; called by muse, mutect2, varscan2
- BEST3 | c.1353G>T p.K451N | Missense Mutation (SNP) | VAF 100/110 reads (91%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as COSV58299647; called by muse, mutect2, varscan2
- C12orf40 | c.1843G>A p.D615N | Missense Mutation (SNP) | VAF 35/80 reads (44%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as COSV61130243; called by muse, mutect2, varscan2
- C9orf78 | c.542+2T>G p.X181_splice | Splice Site (SNP) | VAF 42/102 reads (41%) | catalogued as COSV100204749; called by muse, mutect2, varscan2
- CCAR1 | c.813G>T p.Q271H | Missense Mutation (SNP) | VAF 32/69 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.496); catalogued as COSV56268257, COSV99771578; called by muse, mutect2, varscan2
- CCNF | c.1008G>T p.E336D | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.53); PolyPhen benign (0.007); catalogued as COSV53538564; called by muse, mutect2, varscan2
- CD109 | c.627A>T p.Q209H | Missense Mutation (SNP) | VAF 45/52 reads (87%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.722); catalogued as rs776870550, COSV54646780; called by muse, mutect2, varscan2
- CER1 | c.335T>C p.L112P | Missense Mutation (SNP) | VAF 58/149 reads (39%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as COSV66603014; called by muse, mutect2, varscan2
- CKAP5 | c.5737C>G p.P1913A (on ENST00000529230 / NM_001008938.4; = p.P1853A on NM_014756.3) | Missense Mutation (SNP) | VAF 40/94 reads (43%) | SIFT tolerated (0.64); PolyPhen benign (0.015); catalogued as COSV56365307; called by muse, mutect2, varscan2
- CLCN4 | c.1092G>C p.R364S | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT tolerated (0.35); PolyPhen benign (0.005); catalogued as COSV66465601; called by muse, mutect2, varscan2
- COL5A2 | c.3662G>T p.G1221V | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66408087, COSV66408644; called by muse, mutect2, varscan2
- COLQ | c.1226A>C p.H409P | Missense Mutation (SNP) | VAF 53/203 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.356); catalogued as COSV67524285; called by muse, mutect2, varscan2
- CORIN | c.1848T>G p.C616W | Missense Mutation (SNP) | VAF 75/267 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56688233; called by muse, mutect2, varscan2
- CORO2A | c.541G>C p.D181H | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV59662443; called by muse, mutect2, varscan2
- CSMD1 | c.1769C>T p.T590M (on ENST00000520002; = p.T589M on NM_033225.6) | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766292308, COSV59296579; called by muse, mutect2, varscan2
- CYRIA | c.703G>T p.E235* | Nonsense Mutation (SNP) | VAF 79/92 reads (86%) | catalogued as COSV62864368, COSV62866545; called by muse, mutect2, varscan2
- CYTH3 | c.557C>A p.S186Y | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as COSV63437882; called by muse, mutect2, varscan2
- DEFB113 | c.122C>T p.A41V | Missense Mutation (SNP) | VAF 63/212 reads (30%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.003); catalogued as rs779271969, COSV59037309; called by muse, mutect2, varscan2
- DENND6A | c.1341C>G p.F447L | Missense Mutation (SNP) | VAF 26/27 reads (96%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV60767904; called by muse, mutect2, varscan2
- DGCR2 | c.510C>G p.D170E | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.04); catalogued as COSV54217192; called by muse, mutect2, varscan2
- DNAH7 | c.8782A>T p.N2928Y | Missense Mutation (SNP) | VAF 25/165 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.195); catalogued as COSV56756294; called by muse, mutect2, varscan2
- DNTT | c.186G>T p.R62S | Missense Mutation (SNP) | VAF 37/94 reads (39%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.949); catalogued as rs764403515, COSV64522782; called by muse, mutect2, varscan2
- EMSY | c.1128C>G p.I376M | Missense Mutation (SNP) | VAF 50/98 reads (51%) | SIFT deleterious (0.03); PolyPhen benign (0.143); catalogued as COSV58258345; called by muse, mutect2, varscan2
- ENOSF1 | c.506C>T p.A169V (on ENST00000340116 / NM_001354066.2; = p.A121V on NM_017512.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); catalogued as rs763758268, COSV51891382, COSV99201147; called by muse, mutect2, varscan2
- EPHA5 | c.265G>A p.V89M | Missense Mutation (SNP) | VAF 41/88 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.114); catalogued as COSV56635889; called by muse, mutect2, varscan2
- FAM102B | c.930A>G p.I310M | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64239458; called by muse, mutect2, varscan2
- FAR2 | c.877G>T p.A293S | Missense Mutation (SNP) | VAF 52/62 reads (84%) | SIFT tolerated (0.06); PolyPhen benign (0.411); catalogued as COSV51724147; called by muse, mutect2, varscan2
- FBXL18 | c.1082C>T p.S361L | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs760978099, COSV66665626; called by muse, mutect2, varscan2
- FOCAD | c.1349C>T p.A450V | Missense Mutation (SNP) | VAF 62/133 reads (47%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs537746068, COSV58095423; called by muse, mutect2, varscan2
- FOXP3 | c.315+2T>C p.X105_splice | Splice Site (SNP) | VAF 25/80 reads (31%) | catalogued as COSV100873264; called by muse, mutect2, varscan2
- FRMD3 | c.517A>G p.I173V | Missense Mutation (SNP) | VAF 85/172 reads (49%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs111374752, COSV58456684; called by muse, mutect2, varscan2
- FRMPD4 | c.3179A>G p.E1060G | Missense Mutation (SNP) | VAF 45/104 reads (43%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); catalogued as COSV66212459; called by muse, mutect2, varscan2
- G2E3 | c.1349G>T p.G450V | Missense Mutation (SNP) | VAF 54/133 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52839142; called by muse, mutect2, varscan2
- GNAT3 | c.393G>A p.W131* | Nonsense Mutation (SNP) | VAF 54/191 reads (28%) | catalogued as COSV68068147; called by muse, mutect2, varscan2
- GPC5 | c.506G>A p.S169N | Missense Mutation (SNP) | VAF 35/89 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.06); catalogued as COSV65585129; called by muse, mutect2, varscan2
- GPR132 | c.853A>G p.R285G | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.129); catalogued as COSV61677704; called by muse, mutect2, varscan2
- GPR179 | c.1868C>T p.T623M (on ENST00000621958; = p.T622M on NM_001004334.4) | Missense Mutation (SNP) | VAF 75/84 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1349762430; called by muse, mutect2, varscan2
- GSDME | c.1352T>A p.L451* | Nonsense Mutation (SNP) | VAF 25/95 reads (26%) | catalogued as COSV56036518; called by muse, mutect2, varscan2
- HELQ | c.2312A>C p.D771A | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as COSV55024477; called by muse, mutect2, varscan2
- HLA-B | c.911C>G p.S304C | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.806); catalogued as COSV69520743; called by muse, mutect2, varscan2
- HSPA14 | c.1456G>A p.G486R | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65684090; called by muse, mutect2, varscan2
- INTS7 | c.2207G>A p.G736E | Missense Mutation (SNP) | VAF 57/140 reads (41%) | SIFT tolerated (0.69); PolyPhen probably damaging (0.999); catalogued as COSV65343887; called by muse, mutect2, varscan2
- KDM5A | c.2815G>C p.E939Q | Missense Mutation (SNP) | VAF 29/41 reads (71%) | SIFT deleterious (0); PolyPhen benign (0.217); catalogued as COSV66991054; called by muse, mutect2, varscan2
- KIAA1210 | c.4559G>T p.S1520I | Missense Mutation (SNP) | VAF 40/111 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.599); catalogued as COSV68176114; called by muse, mutect2, varscan2
- KIF5C | c.2774C>A p.P925H | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV68480286; called by muse, mutect2, varscan2
- KRT28 | c.1037C>T p.A346V | Missense Mutation (SNP) | VAF 49/63 reads (78%) | SIFT deleterious (0.01); PolyPhen benign (0.426); catalogued as rs150448547; called by muse, mutect2, varscan2
- LAMC2 | c.1666G>C p.G556R | Missense Mutation (SNP) | VAF 8/143 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99917947; called by muse, mutect2
- LGSN | c.1058C>T p.A353V | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.836); catalogued as COSV65726500; called by muse, mutect2, varscan2
- LIG3 | c.1013C>G p.P338R | Missense Mutation (SNP) | VAF 11/16 reads (69%) | SIFT tolerated (0.34); PolyPhen benign (0.102); catalogued as COSV52006474; called by muse, mutect2, varscan2
- LMOD1 | c.928G>C p.E310Q | Missense Mutation (SNP) | VAF 88/338 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.188); catalogued as rs760795096, COSV100939133, COSV66172093; called by muse, mutect2, varscan2
- LPAR1 | c.1027C>T p.R343C | Missense Mutation (SNP) | VAF 156/328 reads (48%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.793); catalogued as rs1199624602, COSV62687565; called by muse, mutect2, varscan2
- LSR | c.1636T>G p.S546A (on ENST00000361790; = p.S527A on NM_015925.6) | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as COSV55886600; called by muse, mutect2, varscan2
- MAGI3 | c.3508A>C p.K1170Q | Missense Mutation (SNP) | VAF 44/85 reads (52%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.59); catalogued as COSV56830570; called by muse, mutect2, varscan2
- MATN1 | c.1209C>T p.G403= | Splice Region (SNP) | VAF 35/42 reads (83%) | catalogued as COSV65650267; called by muse, mutect2, varscan2
- MMP11 | c.1323G>C p.Q441H | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.954); catalogued as COSV53155604; called by muse, mutect2, varscan2
- MOB4 | c.295C>G p.Q99E | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.833); catalogued as COSV52095312; called by muse, mutect2, varscan2
- MPP1 | c.1061A>G p.Y354C | Missense Mutation (SNP) | VAF 120/299 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV65729289; called by muse, mutect2, varscan2
- MRPL13 | c.370A>G p.R124G | Missense Mutation (SNP) | VAF 33/170 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV60366870; called by muse, mutect2, varscan2
- MRPL40 | c.396G>C p.E132D | Missense Mutation (SNP) | VAF 56/102 reads (55%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.807); catalogued as COSV54273253; called by muse, mutect2, varscan2
- MUC17 | c.11350T>A p.S3784T | Missense Mutation (SNP) | VAF 40/58 reads (69%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.501); catalogued as COSV60283009; called by muse, mutect2, varscan2
- MYH14 | c.2723G>T p.R908L | Missense Mutation (SNP) | VAF 48/134 reads (36%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV99224092; called by muse, mutect2
- NAT9 | c.452C>T p.P151L | Missense Mutation (SNP) | VAF 33/98 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.232); catalogued as COSV52852767; called by muse, mutect2, varscan2
- NAV2 | c.6425G>C p.R2142P (on ENST00000396087 / NM_001244963.2; = p.R2083P on NM_145117.5) | Missense Mutation (SNP) | VAF 53/115 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60657428, COSV60661985; called by muse, mutect2, varscan2
- NCKAP1L | c.62G>A p.R21H | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs759163371, COSV53203836; called by muse, mutect2, varscan2
- NEK5 | c.187A>G p.I63V | Missense Mutation (SNP) | VAF 60/120 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs1433623425, COSV62879256; called by muse, mutect2, varscan2
- NOD1 | c.2721G>T p.Q907H | Missense Mutation (SNP) | VAF 30/53 reads (57%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV56111358; called by muse, mutect2, varscan2
- NRXN3 | c.26G>A p.R9Q | Missense Mutation (SNP) | VAF 14/266 reads (5%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.027); catalogued as COSV99819012, COSV99821792; called by muse, mutect2
- OR11L1 | c.127G>T p.V43F | Missense Mutation (SNP) | VAF 43/171 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.022); catalogued as COSV63313921; called by muse, mutect2, varscan2
- OR2AG1 | c.382C>T p.H128Y | Missense Mutation (SNP) | VAF 9/126 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.033); catalogued as COSV100264984; called by muse, mutect2
- OR6K2 | c.735C>A p.H245Q | Missense Mutation (SNP) | VAF 138/398 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV62743247, COSV62743901; called by muse, mutect2, varscan2
- OSBPL3 | c.160C>T p.Q54* | Nonsense Mutation (SNP) | VAF 143/227 reads (63%) | catalogued as COSV57654273; called by muse, mutect2, varscan2
- PACSIN1 | c.1166G>A p.R389H | Missense Mutation (SNP) | VAF 41/57 reads (72%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs767367808, COSV55059121; called by muse, mutect2, varscan2
- PCDH11X | c.1943G>T p.G648V | Missense Mutation (SNP) | VAF 32/66 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.772); catalogued as COSV53451278; called by muse, mutect2, varscan2
- PCDH19 | c.739G>C p.V247L | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.073); catalogued as COSV55259401, COSV55266488; called by muse, mutect2, varscan2
- PCDHB5 | c.1023C>A p.D341E | Missense Mutation (SNP) | VAF 57/63 reads (90%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV50648269; called by muse, mutect2, varscan2
- PEX13 | c.31C>T p.P11S | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV99693023; called by muse, mutect2
- PJA1 | c.1613T>C p.M538T (on ENST00000361478 / NM_145119.4; = p.M350T on NM_022368.5) | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV64052812; called by muse, mutect2, varscan2
- PLA2G7 | c.187T>A p.Y63N | Missense Mutation (SNP) | VAF 93/324 reads (29%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.47); catalogued as COSV51258955; called by muse, mutect2, varscan2
- PLXNA1 | c.353T>A p.L118Q | Missense Mutation (SNP) | VAF 9/11 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52523461; called by muse, mutect2, varscan2
- PNPLA1 | c.1579C>G p.P527A (on ENST00000394571 / NM_001374623.1; = p.P432A on NM_173676.2) | Missense Mutation (SNP) | VAF 41/131 reads (31%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); catalogued as COSV57233123; called by muse, varscan2
- PROM1 | c.2059C>G p.P687A | Missense Mutation (SNP) | VAF 101/203 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as COSV71699229; called by muse, mutect2, varscan2
- PROX1 | c.1565C>T p.T522M | Missense Mutation (SNP) | VAF 53/190 reads (28%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.714); catalogued as COSV54776444, COSV54776998; called by muse, mutect2, varscan2
- PXDNL | c.1180G>T p.G394C | Missense Mutation (SNP) | VAF 44/93 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62482239; called by muse, mutect2, varscan2
- RANBP3L | c.578C>G p.S193* | Nonsense Mutation (SNP) | VAF 46/119 reads (39%) | catalogued as COSV56954812; called by muse, mutect2, varscan2
- RBM26 | c.1924C>G p.P642A (on ENST00000438737 / NM_001366735.2; = p.P639A on NM_022118.5) | Missense Mutation (SNP) | VAF 50/119 reads (42%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.543); catalogued as COSV57391241; called by muse, mutect2, varscan2
- RIMBP2 | c.3037T>G p.F1013V | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55466023, COSV55470989, COSV55480263; called by muse, mutect2, varscan2
- RIMS1 | c.86C>G p.T29S | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV53445050; called by muse, mutect2, varscan2
- ROCK2 | c.3560G>A p.S1187N | Missense Mutation (SNP) | VAF 54/73 reads (74%) | SIFT tolerated (0.16); PolyPhen benign (0.097); catalogued as COSV59954861; called by muse, mutect2, varscan2
- RRN3 | c.667G>C p.E223Q | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.146); catalogued as COSV52213682, COSV52214438; called by muse, mutect2, varscan2
- SCG3 | c.310A>G p.N104D | Missense Mutation (SNP) | VAF 53/64 reads (83%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.215); catalogued as rs1397529071, COSV55020405; called by muse, mutect2, varscan2
- SEC31A | c.130G>C p.E44Q | Missense Mutation (SNP) | VAF 46/108 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); catalogued as COSV58872605, COSV58879764; called by muse, mutect2, varscan2
- SEC63 | c.185G>A p.R62Q | Missense Mutation (SNP) | VAF 84/213 reads (39%) | SIFT tolerated (0.61); PolyPhen benign (0.009); catalogued as rs754641338, COSV64598920; called by muse, mutect2, varscan2
- SLC22A2 | c.692G>A p.R231Q | Missense Mutation (SNP) | VAF 63/156 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.19); catalogued as rs774295115, COSV65265669; called by muse, mutect2, varscan2
- SLC27A1 | c.631G>A p.E211K | Missense Mutation (SNP) | VAF 22/207 reads (11%) | SIFT tolerated (0.46); PolyPhen benign (0.015); catalogued as rs369713751; called by muse, mutect2
- SPP1 | c.320A>C p.D107A (on ENST00000395080 / NM_001040058.2; = p.D93A on NM_000582.2) | Missense Mutation (SNP) | VAF 48/91 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.836); catalogued as COSV52951513; called by muse, mutect2, varscan2
- STK4 | c.1408C>T p.R470W | Missense Mutation (SNP) | VAF 41/131 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs768691855, COSV65669622, COSV65670574; called by muse, mutect2, varscan2
- TBP | c.713C>A p.A238D | Missense Mutation (SNP) | VAF 136/249 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57831257; called by muse, mutect2, varscan2
- TG | c.1118C>T p.S373F | Missense Mutation (SNP) | VAF 23/169 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.909); catalogued as COSV55069248; called by muse, mutect2, varscan2
- TMC2 | c.598A>G p.K200E | Missense Mutation (SNP) | VAF 147/310 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV62650729; called by muse, mutect2, varscan2
- TMC3 | c.1790G>A p.S597N | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.884); catalogued as COSV63922527; called by muse, mutect2, varscan2
- TRIM65 | c.475C>G p.L159V | Missense Mutation (SNP) | VAF 15/101 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.132); catalogued as COSV53932541; called by muse, mutect2, varscan2
- TTN | c.84160G>A p.V28054I (on ENST00000591111; = p.V20630I on NM_003319.4) | Missense Mutation (SNP) | VAF 48/148 reads (32%) | PolyPhen probably damaging (0.99); catalogued as COSV100629239; called by muse, mutect2, varscan2
- TTN | c.37246G>T p.A12416S (on ENST00000591111; = p.A4992S on NM_003319.4) | Missense Mutation (SNP) | VAF 9/26 reads (35%) | PolyPhen benign (0.436); catalogued as COSV59940522, COSV60036938; called by muse, mutect2, varscan2
- TTN | c.2852A>T p.N951I (on ENST00000591111; = p.N905I on NM_003319.4) | Missense Mutation (SNP) | VAF 9/33 reads (27%) | PolyPhen possibly damaging (0.885); catalogued as COSV59940566; called by muse, mutect2, varscan2
- UGT1A3 | c.418C>A p.H140N | Missense Mutation (SNP) | VAF 256/272 reads (94%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as COSV59384478; called by muse, mutect2, varscan2
- VIP | c.82C>T p.L28F | Missense Mutation (SNP) | VAF 7/176 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as COSV100923965; called by muse, mutect2
- VPS35L | c.128C>G p.S43* | Nonsense Mutation (SNP) | VAF 13/37 reads (35%) | catalogued as COSV51979175; called by muse, mutect2, varscan2
- XPO5 | c.651G>A p.A217= | Splice Region (SNP) | VAF 24/58 reads (41%) | catalogued as rs765845766, COSV54828311; called by muse, mutect2, varscan2
- YEATS2 | c.1667C>G p.S556C | Missense Mutation (SNP) | VAF 102/184 reads (55%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.781); catalogued as COSV59363132, COSV59372873; called by muse, mutect2, varscan2
- ZBTB24 | c.1490T>G p.L497* | Nonsense Mutation (SNP) | VAF 40/86 reads (47%) | catalogued as COSV57781473; called by muse, mutect2, varscan2
- ZFHX4 | c.1591G>A p.D531N | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as COSV50632102, COSV51494233; called by muse, mutect2, varscan2
- ZKSCAN7 | c.520G>T p.G174C | Missense Mutation (SNP) | VAF 58/65 reads (89%) | SIFT deleterious (0.01); PolyPhen benign (0.042); catalogued as COSV56272054; called by muse, mutect2, varscan2
- ZNF536 | c.1051G>A p.G351S | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV62819589, COSV62820183, COSV62820593; called by muse, mutect2, varscan2
- ZNF544 | c.1358T>C p.V453A | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.028); catalogued as COSV54134832; called by muse, mutect2, varscan2
- ZUP1 | c.1055C>G p.S352C | Missense Mutation (SNP) | VAF 77/184 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.449); catalogued as COSV63944141; called by muse, mutect2, varscan2
- AGFG2 | c.1263_1283del p.F422_L428del | In Frame Del (DEL) | VAF 30/67 reads (45%) | called by mutect2, pindel, varscan2
- BRWD1 | c.6510_6514del p.C2170* | Nonsense Mutation (DEL) | VAF 101/249 reads (41%) | called by mutect2, pindel, varscan2
- CFAP47 | c.1313del p.N438Ifs*8 | Frame Shift Del (DEL) | VAF 46/134 reads (34%) | called by mutect2, pindel, varscan2
- DCAF6 | c.2513_2518+19del p.X838_splice (on ENST00000312263 / NM_001349778.1; = p.X858_splice on NM_018442.3 and 4 other RefSeq transcripts) | Splice Site (DEL) | VAF 63/288 reads (22%) | called by mutect2, pindel, varscan2
- DIP2C | c.857_859del p.E286del | In Frame Del (DEL) | VAF 11/77 reads (14%) | called by mutect2, pindel, varscan2
- FAN1 | c.1656_1674del p.F552Lfs*55 | Frame Shift Del (DEL) | VAF 27/76 reads (36%) | called by mutect2, pindel, varscan2
- FOCAD | c.5132del p.P1711Qfs*66 | Frame Shift Del (DEL) | VAF 7/34 reads (21%) | called by mutect2, pindel, varscan2
- MROH1 | c.30_45del p.S11Pfs*51 | Frame Shift Del (DEL) | VAF 9/74 reads (12%) | called by mutect2, pindel, varscan2
- PNPLA1 | c.1578del p.K526Nfs*? (on ENST00000394571 / NM_001374623.1; = p.K431Nfs*11 on NM_173676.2) | Frame Shift Del (DEL) | VAF 37/149 reads (25%) | called by pindel, varscan2
- SH3BP4 | c.169_182dup p.I61Mfs*5 | Frame Shift Ins (INS) | VAF 23/78 reads (29%) | called by mutect2, varscan2
- TARBP2 | c.977_1002del p.L326Hfs*16 (on ENST00000266987 / NM_134323.2; = p.L305Hfs*16 on NM_004178.4) | Frame Shift Del (DEL) | VAF 10/25 reads (40%) | called by mutect2, pindel, varscan2
- ADCY8 | c.2788C>A p.R930= | Silent (SNP) | VAF 58/306 reads (19%) | catalogued as rs765725170, COSV53897461, COSV53900478; called by muse, mutect2, varscan2
- ARHGAP35 | c.3921G>T p.L1307= | Silent (SNP) | VAF 13/61 reads (21%) | catalogued as COSV68329812; called by muse, mutect2, varscan2
- C16orf54 | c.213C>T p.T71= | Silent (SNP) | VAF 20/51 reads (39%) | catalogued as COSV61476664; called by muse, mutect2, varscan2
- C1orf74 | c.795G>C p.P265= | Silent (SNP) | VAF 45/124 reads (36%) | catalogued as COSV50551013; called by muse, mutect2, varscan2
- CACNA1A | c.1308C>T p.P436= | Silent (SNP) | VAF 180/302 reads (60%) | catalogued as rs376451601; ClinVar: likely benign; called by muse, mutect2, varscan2
- CARF | c.744T>A p.R248= | Silent (SNP) | VAF 45/153 reads (29%) | catalogued as COSV57546913; called by muse, mutect2, varscan2
- CCDC198 | c.201C>T p.N67= | Silent (SNP) | VAF 47/100 reads (47%) | catalogued as COSV53601573; called by muse, mutect2, varscan2
- CDH22 | c.1119C>A p.G373= | Silent (SNP) | VAF 28/69 reads (41%) | catalogued as COSV64836865; called by muse, mutect2, varscan2
- CUL3 | c.2016C>G p.V672= | Silent (SNP) | VAF 45/98 reads (46%) | catalogued as COSV52362489; called by muse, mutect2, varscan2
- DISP1 | c.3297C>G p.P1099= | Silent (SNP) | VAF 25/68 reads (37%) | catalogued as COSV52656220; called by muse, mutect2, varscan2
- FAAH2 | c.369C>T p.F123= | Silent (SNP) | VAF 75/160 reads (47%) | catalogued as COSV66506143, COSV66506295; called by muse, mutect2, varscan2
- FCRL5 | c.435T>G p.L145= | Silent (SNP) | VAF 32/120 reads (27%) | catalogued as COSV62512815; called by muse, mutect2, varscan2
- ITGA10 | c.2022C>G p.V674= | Silent (SNP) | VAF 25/91 reads (27%) | catalogued as COSV65196259, COSV65196461; called by muse, mutect2, varscan2
- KCND2 | c.1830A>G p.G610= | Silent (SNP) | VAF 31/90 reads (34%) | catalogued as COSV58573146; called by muse, mutect2, varscan2
- KIAA0232 | c.3651A>G p.E1217= | Silent (SNP) | VAF 35/73 reads (48%) | catalogued as COSV100300603, COSV56923912; called by muse, mutect2, varscan2
- LSG1 | c.1314T>C p.C438= | Silent (SNP) | VAF 41/173 reads (24%) | catalogued as COSV54569008; called by muse, mutect2, varscan2
- NPIPB15 | c.1269G>A p.P423= | Silent (SNP) | VAF 13/71 reads (18%) | catalogued as rs1246674270, COSV70436881; called by muse, mutect2, varscan2
- NR2F6 | c.189G>C p.S63= | Silent (SNP) | VAF 5/12 reads (42%) | catalogued as rs1177973852, COSV52243083; called by muse, mutect2, varscan2
- OGG1 | c.1029G>A p.P343= | Silent (SNP) | VAF 181/194 reads (93%) | catalogued as rs776858974, COSV56537707; called by muse, mutect2, varscan2
- OR10S1 | c.75C>T p.F25= | Silent (SNP) | VAF 22/68 reads (32%) | catalogued as COSV104440479, COSV73342700; called by muse, mutect2, varscan2
- PCDHA1 | c.2295C>G p.P765= | Silent (SNP) | VAF 42/51 reads (82%) | catalogued as COSV65373190; called by muse, mutect2, varscan2
- PENK | c.96G>A p.T32= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as COSV59239938; called by muse, varscan2
- PLP2 | c.24G>A p.S8= | Silent (SNP) | VAF 27/47 reads (57%) | catalogued as COSV66239428; called by muse, mutect2, varscan2
- PLXNA4 | c.2682C>G p.V894= | Silent (SNP) | VAF 39/134 reads (29%) | catalogued as COSV100322121, COSV58112695; called by muse, mutect2, varscan2
- RBL1 | c.387T>C p.F129= | Silent (SNP) | VAF 55/61 reads (90%) | catalogued as COSV60328856; called by muse, mutect2, varscan2
- RGS11 | c.346A>C p.R116= (on ENST00000397770 / NM_183337.3; = p.R95= on NM_003834.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 4/10 reads (40%) | catalogued as rs970263096, COSV51451761; called by muse, mutect2, varscan2
- SCN9A | c.4437G>A p.K1479= (on ENST00000303354; = p.K1468= on NM_002977.3) | Silent (SNP) | VAF 90/270 reads (33%) | catalogued as rs267598972, COSV57603736; called by muse, mutect2, varscan2
- SEC63 | c.240T>G p.L80= | Silent (SNP) | VAF 48/109 reads (44%) | catalogued as COSV64598914; called by muse, mutect2, varscan2
- SIPA1L2 | c.4515G>C p.R1505= | Silent (SNP) | VAF 68/228 reads (30%) | catalogued as COSV53385616; called by muse, mutect2, varscan2
- SPATA18 | c.951G>A p.A317= | Silent (SNP) | VAF 31/70 reads (44%) | catalogued as COSV54642522; called by muse, mutect2, varscan2
- SYNPO2 | c.42G>T p.G14= | Silent (SNP) | VAF 166/173 reads (96%) | catalogued as COSV61107933; called by muse, mutect2, varscan2
- TACC2 | c.6546T>C p.G2182= (on ENST00000334433; = p.G260= on NM_006997.4) | Silent (SNP) | VAF 8/118 reads (7%) | catalogued as COSV99587702; called by muse, mutect2
- TTC21A | c.1446A>G p.P482= | Silent (SNP) | VAF 75/89 reads (84%) | catalogued as COSV57183738; called by muse, mutect2, varscan2
- TTN | c.96171T>C p.V32057= (on ENST00000591111; = p.V24633= on NM_003319.4) | Silent (SNP) | VAF 65/92 reads (71%) | catalogued as COSV59940476, COSV59970882; called by muse, mutect2, varscan2
- XIAP | c.1461C>G p.V487= | Silent (SNP) | VAF 51/123 reads (41%) | catalogued as COSV63021873; called by muse, mutect2, varscan2
- ZFP69 | c.978C>T p.P326= | Silent (SNP) | VAF 5/94 reads (5%) | catalogued as COSV101018380; called by muse, mutect2
- ZFPM2 | c.2829G>A p.K943= | Silent (SNP) | VAF 16/51 reads (31%) | catalogued as rs752360592, COSV65872905; called by muse, mutect2, varscan2
- C8orf31 | n.566G>T | RNA (SNP) | VAF 41/177 reads (23%) | called by muse, mutect2, varscan2
- FSTL4 | c.161-26662G>A | Intron (SNP) | VAF 112/131 reads (85%) | catalogued as rs567603326, COSV54766195; called by muse, mutect2, varscan2
- MARVELD3 | chr16:71640853 del GGCAGGC | 3'Flank (DEL) | VAF 9/34 reads (26%) | called by mutect2, pindel, varscan2
- MIR193A | n.88G>T | RNA (SNP) | VAF 13/14 reads (93%) | called by muse, mutect2, varscan2
